Somatic mutation profile of tumor specimen MP2PRT-PARGGX-TMP1-A (aliquot MP2PRT-PARGGX-TMP1-A-1-0-D-A82K-36) from MP2PRT case MP2PRT-PARGGX, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.4 years (1,982 days).
Specimen MP2PRT-PARGGX-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 019dc537-574a-4f65-a736-dc7a7cfa534f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARGGX-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARGGX-NB1-A-1-0-D-A82K-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/004076c4-d477-48da-8b11-539234a151d6

The open-access MAF lists 34 somatic variants for this specimen: 26 protein-altering or splice-affecting, 8 silent.
By variant classification: Missense Mutation 25, Silent 8, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1861A>C p.N621H (on ENST00000288602 / NM_001374244.1; = p.N581H on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 135/333 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.55); catalogued as rs180177040, CM060878, COSV56062673, COSV56077649, COSV56286119; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- CCDC196 | c.358G>A p.E120K | Missense Mutation (SNP) | VAF 135/380 reads (36%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.017); catalogued as rs866116538; called by muse, mutect2, varscan2
- CPSF2 | c.1362C>G p.F454L | Missense Mutation (SNP) | VAF 111/413 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.629); catalogued as COSV54097244; called by muse, mutect2, varscan2
- ERBB2 | c.1429G>A p.V477M | Missense Mutation (SNP) | VAF 284/715 reads (40%) | SIFT tolerated (0.2); PolyPhen benign (0.234); catalogued as rs755121772; called by muse, varscan2
- FAT1 | c.8050G>C p.E2684Q | Missense Mutation (SNP) | VAF 24/432 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.11); catalogued as rs748166431, COSV71672478, COSV71676217; called by muse, mutect2
- NSD2 | c.3295G>A p.E1099K | Missense Mutation (SNP) | VAF 171/404 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs772470710, COSV56386422; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SMPDL3A | c.679G>A p.A227T | Missense Mutation (SNP) | VAF 189/513 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63755427; called by muse, mutect2, varscan2
- ST14 | c.2074C>T p.R692C | Missense Mutation (SNP) | VAF 335/815 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53836621; called by muse, mutect2, varscan2
- ADAM8 | c.2074C>T p.P692S | Missense Mutation (SNP) | VAF 220/729 reads (30%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.612); called by muse, mutect2, varscan2
- ARMC4 | c.2999T>A p.M1000K | Missense Mutation (SNP) | VAF 162/382 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- DNAH8 | c.3911A>C p.D1304A | Missense Mutation (SNP) | VAF 105/265 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- ELOA3C | c.634G>A p.G212S | Missense Mutation (SNP) | VAF 283/2608 reads (11%) | SIFT tolerated (0.4); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- GRIA1 | c.188A>G p.N63S | Missense Mutation (SNP) | VAF 180/459 reads (39%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, varscan2
- INPP4A | c.1929G>A p.M643I (on ENST00000074304 / NM_001134224.1; = p.M604I on NM_001566.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 220/710 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.228); called by muse, mutect2, varscan2
- LMBR1 | c.1402C>G p.H468D | Missense Mutation (SNP) | VAF 109/352 reads (31%) | SIFT tolerated (0.59); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PDCD11 | c.283G>A p.E95K | Missense Mutation (SNP) | VAF 127/490 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PHLDA1 | c.250G>C p.E84Q | Missense Mutation (SNP) | VAF 409/1072 reads (38%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- PON1 | c.782C>G p.S261C | Missense Mutation (SNP) | VAF 37/296 reads (13%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.682); called by muse, mutect2, varscan2
- POTEI | c.849A>C p.Q283H | Missense Mutation (SNP) | VAF 55/427 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.19); called by muse, mutect2, varscan2
- POTEJ | c.738A>C p.Q246H | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.19); called by muse, mutect2, varscan2
- RNF32 | c.946G>A p.E316K | Missense Mutation (SNP) | VAF 221/770 reads (29%) | SIFT tolerated (0.47); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TTC6 | c.2545G>T p.E849* | Nonsense Mutation (SNP) | VAF 42/428 reads (10%) | called by muse, mutect2
- UVSSA | c.1291C>A p.L431M | Missense Mutation (SNP) | VAF 194/482 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- WDR17 | c.1484G>C p.R495T | Missense Mutation (SNP) | VAF 22/324 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2
- ZNF709 | c.1651G>A p.E551K | Missense Mutation (SNP) | VAF 192/650 reads (30%) | SIFT tolerated (0.4); PolyPhen benign (0.318); called by muse, mutect2, varscan2
- ZNF709 | c.1399G>A p.E467K | Missense Mutation (SNP) | VAF 166/640 reads (26%) | SIFT tolerated (0.33); PolyPhen benign (0.237); called by muse, varscan2
- CCDC117 | c.228G>A p.E76= | Silent (SNP) | VAF 181/475 reads (38%) | called by muse, mutect2, varscan2
- CES4A | c.33C>G p.L11= | Silent (SNP) | VAF 198/700 reads (28%) | called by muse, mutect2, varscan2
- HUNK | c.1062G>A p.K354= | Silent (SNP) | VAF 62/564 reads (11%) | called by muse, mutect2, varscan2
- KRT25 | c.810G>A p.A270= | Silent (SNP) | VAF 194/489 reads (40%) | catalogued as COSV100379948, COSV56446033; called by muse, mutect2, varscan2
- KRT71 | c.1005C>A p.G335= | Silent (SNP) | VAF 101/347 reads (29%) | catalogued as rs145210819; called by muse, mutect2, varscan2
- PCSK5 | c.909C>A p.L303= | Silent (SNP) | VAF 60/518 reads (12%) | catalogued as COSV65098871; called by muse, mutect2, varscan2
- SLC22A6 | c.1494C>T p.S498= | Silent (SNP) | VAF 168/594 reads (28%) | catalogued as rs751689928; called by muse, varscan2
- SPNS2 | c.1131C>T p.G377= | Silent (SNP) | VAF 230/542 reads (42%) | catalogued as rs780488135, COSV61229343; called by muse, mutect2, varscan2
